Gene-level copy-number profile of tumor specimen ALCH-B25U-TTP1-A from ALCHEMIST case ALCH-B25U, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.5 years (23,575 days).
Specimen ALCH-B25U-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 85c8c949-13f5-4bc8-83dc-d8f27267be7d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B25U-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/d7656efa-f242-4bf8-b22f-bbd547412827

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 2,481; copy number 2: 54,826; copy number 3: 1,031; copy number 4: 15; copy number 7: 4; copy number 9: 1; copy number 13: 1; copy number 16: 1; copy number 20: 1.

Homozygous deletions (total copy number 0; autosomes only): 32 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:62,189,131–62,319,434, 7 genes (within-gene range 0–2): PIGPP2, RPS15AP7, L1TD1, AL162739.1, Y_RNA, KANK4, RNU6-371P.
- chr1:180,154,869–180,204,030, 1 gene: QSOX1.
- chr2:97,713,576–97,739,862, 1 gene: ZAP70.
- chr4:1,617,915–1,684,261, 2 genes (within-gene range 0–2): FAM53A, Y_RNA.
- chr8:46,028,804–46,028,892, 1 gene: AC118650.1.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr10:49,734,641–49,762,379, 1 gene: OGDHL.
- chr10:86,654,547–86,666,848, 1 gene: OPN4.
- chr15:41,828,092–41,848,155, 3 genes (within-gene range 0–2): JMJD7, JMJD7-PLA2G4B, PLA2G4B.
- chr16:77,190,835–77,213,215, 2 genes (within-gene range 0–2): MON1B, SYCE1L.
- chr17:62,627,670–62,808,344, 7 genes: MRC2, Y_RNA, AC080038.3, RNU6-446P, AC005821.1, MARCHF10, AC005821.2.
- chr19:58,034,025–58,054,631, 3 genes: ZSCAN1, LETM1P2, HNRNPDLP4.
- chr20:25,284,915–25,285,588, 1 gene (within-gene range 0–2): AL121772.3.
- chr21:9,053,122–9,059,060, 1 gene: CR392039.4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,280,436–1,292,029, 1 gene, copy number 13: SCNN1D.
- chr16:28,637,654–28,740,781, 5 genes, copy number 7–9: NPIPB8, AC145285.4, EIF3C, CDC37P1, MIR6862-2.
- chr21:44,107,373–44,210,114, 2 genes, copy number 16–20 (within-gene range 2–20): PWP2, GATD3A.

Autosomal genes at a single copy (total copy number 1): 2,479. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
